Gene-level copy-number profile of tumor specimen TCGA-22-4595-01A from TCGA case TCGA-22-4595, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.9 years (21,146 days).
Specimen TCGA-22-4595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3130e6d5-370c-40bc-917d-b1784f2b3c56.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4595-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee0679d9-b850-4ca7-8c98-be769bdd5f63

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 30,586; copy number 2: 22,061; copy number 3: 6,099; copy number 4: 893; copy number 5: 82; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4595-01A-01D-1195-01): tumor purity 0.46, ploidy 1.62, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,895,587–248,919,946, 61 genes (broad region; genes not listed).
- chr2:102,736,905–104,757,719, 30 genes (within-gene range 0–4): TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,076 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,232,231–174,022,357, 461 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:10,302,889–31,414,742, 373 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:40,746,481–59,063,766, 257 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr2:59,218,680–60,100,200, 1 gene, copy number 4 (within-gene range 2–4): AC007100.1.
- chr2:59,647,621–61,538,741, 41 genes, copy number 4: RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3.
- chr2:61,803,143–69,437,628, 155 genes, copy number 3–4 (broad region; genes not listed).
- chr2:96,497,646–100,322,501, 87 genes, copy number 3–8 (broad region; genes not listed).
- chr2:101,962,056–102,736,888, 17 genes, copy number 4: LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr2:104,771,282–106,544,297, 40 genes, copy number 3: HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1.
- chr2:117,536,387–123,444,445, 74 genes, copy number 3 (broad region; genes not listed).
- chr3:80,761,042–82,808,021, 16 genes, copy number 3: AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr3:97,759,523–122,892,416, 398 genes, copy number 3–4 (broad region; genes not listed).
- chr3:138,101,478–154,970,223, 286 genes, copy number 3 (broad region; genes not listed).
- chr3:162,486,541–198,222,513, 645 genes, copy number 3–5 (broad region; genes not listed).
- chr5:24,729,379–33,298,066, 107 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr5:36,221,055–45,098,647, 150 genes, copy number 3 (broad region; genes not listed).
- chr6:167,607–33,147,767, 967 genes, copy number 3 (broad region; genes not listed).
- chr7:11,370,365–11,832,198, 1 gene, copy number 3 (within-gene range 2–3): THSD7A.
- chr7:11,820,317–26,376,701, 193 genes, copy number 3 (broad region; genes not listed).
- chr8:150,584–2,623,382, 53 genes, copy number 3: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1.
- chr8:82,862,779–84,142,463, 7 genes, copy number 3 (within-gene range 2–3): AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1.
- chr11:132,284,302–135,075,908, 42 genes, copy number 3: NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:66,767–28,581,511, 729 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr12:41,188,320–42,238,349, 12 genes, copy number 3 (within-gene range 2–3): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2.
- chr13:82,778,208–83,102,335, 1 gene, copy number 3 (within-gene range 2–3): AL445255.1.
- chr13:83,145,540–87,674,235, 33 genes, copy number 3 (within-gene range 2–3): AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1, MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, FO624990.1, DDX6P2, AL445207.1, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG.
- chr13:93,226,807–94,408,020, 1 gene, copy number 3 (within-gene range 2–3): GPC6.
- chr13:93,818,424–96,053,482, 31 genes, copy number 3: GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.
- chr13:96,169,545–96,169,847, 1 gene, copy number 3: RN7SL164P.
- chr14:92,794,305–106,875,071, 651 genes, copy number 3 (broad region; genes not listed).
- chr17:59,422,088–81,183,166, 651 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr17:81,197,393–81,200,288, 1 gene, copy number 3: AC027601.2.
- chr18:316,737–5,004,537, 91 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr19:38,108,500–40,414,793, 131 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr20:87,250–10,673,999, 243 genes, copy number 3–4 (broad region; genes not listed).
- chr20:10,696,949–10,765,286, 2 genes, copy number 3: LINC01752, AL135937.1.
- chr20:18,059,493–23,519,054, 127 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28,177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
